Gene-level copy-number profile of tumor specimen MP2PRT-PAPANB-TMP1-A from MP2PRT case MP2PRT-PAPANB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,173 days).
Specimen MP2PRT-PAPANB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c4e6b247-fbb7-424f-8f7f-d624ece4d9cf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPANB-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,734 have no estimate.
https://portal.gdc.cancer.gov/files/dea52f97-137d-41d9-b89b-ec4786454c4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 296; copy number 2: 37,579; copy number 3: 17,696; copy number 4: 3,207; copy number 5: 57.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,256,396, 1 gene (within-gene range 0–1): TRGJP2.
- chr14:105,851,705–106,122,709, 52 genes (within-gene range 0–3): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–2): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 57 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,203,171–49,246,915, 7 genes, copy number 5: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr10:78,179,174–78,675,109, 2 genes, copy number 5 (within-gene range 4–5): AC012560.1, LINC00595.
- chr10:78,352,597–79,316,528, 7 genes, copy number 5: AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1.
- chr10:132,537,787–133,629,507, 41 genes, copy number 5 (within-gene range 4–5): INPP5A, NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, TUBGCP2, AL360181.2, ZNF511, ZNF511-PRAP1, CALY, BANF1P2, AL360181.1, PRAP1, FUOM, ECHS1, MIR3944, AL360181.4, PAOX, AL360181.3, MTG1, SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P.

Autosomal genes at a single copy (total copy number 1): 261. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
